Somatic mutation profile of tumor specimen MBCProject_4718_T1_WES (aliquot MBCProject_4718_T1_WES_1) from CMI case MBCProject_4718, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.8 years (14,166 days).
Specimen MBCProject_4718_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f668617-65ec-4ebf-aaa2-8238c05d97c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4718_SALIVA (Saliva), aliquot MBCProject_4718_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ddb62dc-f380-4629-a7e8-817905dd6fa3

The open-access MAF lists 77 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, 5'UTR 4, 3'UTR 3, Intron 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 33/230 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917232255; called by muse, mutect2
- ANKRD61 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1053551485; called by muse, mutect2, varscan2
- B4GALNT4 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs200752314, COSV100327376; called by muse, mutect2, varscan2
- CENPF | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65280517; called by muse, mutect2
- COL5A2 | c.1824A>C p.R608S | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1291574149; called by muse, mutect2
- CYP4F22 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs1285696003; called by muse, mutect2, varscan2
- ENTPD5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs753301444; called by muse, varscan2
- GRM8 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV100281042; called by muse, mutect2, varscan2
- KLRB1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs910502797; called by muse, mutect2
- LIPT1 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60739222; called by muse, varscan2
- LRP2 | c.7957A>T p.N2653Y | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1160120152; called by muse, mutect2, varscan2
- NAALADL2 | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV70295770; called by muse, mutect2, varscan2
- NOTCH4 | c.5506G>C p.E1836Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV66679424, COSV66679988, COSV66681239; called by muse, mutect2, varscan2
- OPRM1 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57682065; called by muse, mutect2, varscan2
- PEX1 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50404958; called by muse, mutect2, varscan2
- PRDM1 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs776111636, COSV64844659; called by muse, mutect2, varscan2
- PRPF3 | c.1475A>G p.D492G | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV61394875; called by muse, mutect2
- RGSL1 | c.1986C>A p.F662L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54253827; called by muse, mutect2
- RYR1 | c.5720A>G p.E1907G | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100616498, COSV62110319; called by muse, mutect2
- SORCS3 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV63807550, COSV63825585; called by muse, mutect2, varscan2
- TAAR2 | c.900G>C p.L300F (on ENST00000367931 / NM_001033080.1; = p.L255F on NM_014626.3) | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as rs267600812; called by muse, mutect2, varscan2
- TAAR2 | c.556G>C p.D186H (on ENST00000367931 / NM_001033080.1; = p.D141H on NM_014626.3) | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs746956559, COSV51578443; called by muse, mutect2, varscan2
- TMC8 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753915057; called by muse, mutect2
- TREX2 | c.766G>A p.D256N (on ENST00000334497; = p.D213N on NM_080701.3) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs909494433; called by muse, mutect2
- AKAP9 | c.8224G>C p.E2742Q (on ENST00000359028; = p.E2718Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ATG2A | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATP10D | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2
- CDKN1B | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- CHD2 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CTSA | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- INO80 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KAT6B | c.4099G>C p.E1367Q | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.227); called by muse, mutect2
- NASP | c.2158-2A>T p.X720_splice | Splice Site (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- NDUFS1 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NUMA1 | c.4189_4194dup p.A1397_E1398dup | In Frame Ins (INS) | VAF 8/53 reads (15%) | called by mutect2, varscan2
- PRDX3 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- PRKRA | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- RBM14 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SEC61A2 | c.395del p.V132Afs*2 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- SERTAD3 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOS2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STARD5 | c.100-1G>A p.X34_splice | Splice Site (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- SUPT6H | c.2839G>C p.E947Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2
- TAAR9 | c.927G>C p.L309F | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TMEM67 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNXB | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- TRPM7 | c.1829T>C p.I610T | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.051); called by muse, mutect2
- USP11 | c.1751C>G p.S584* (on ENST00000218348; = p.S541* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- ZNF512 | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ZNF528 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- A4GALT | c.711C>T p.F237= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs530734646, COSV50744415; called by muse, mutect2, varscan2
- APOA5 | c.864C>T p.F288= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- CACNA1E | c.393C>T p.F131= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs1261184698, COSV62381382, COSV62413479; called by mutect2, varscan2
- CSMD2 | c.2703C>T p.D901= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs371160757; called by muse, mutect2, varscan2
- ERRFI1 | c.753G>A p.S251= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs910751550; called by muse, mutect2, varscan2
- H2BC5 | c.222C>T p.I74= | Silent (SNP) | VAF 40/307 reads (13%) | catalogued as rs1358692800, COSV56800766, COSV56803159, COSV99175306; called by muse, mutect2, varscan2
- HMCN2 | c.13611G>A p.G4537= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- SAFB2 | c.2424A>T p.G808= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC15 | c.804C>T p.L268= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- SLC6A3 | c.888A>T p.A296= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- SULT1A1 | c.352C>T p.L118= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- TEN1 | c.219C>T p.Y73= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- TRPM3 | c.165C>G p.L55= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1028283384; called by muse, varscan2
- USP34 | c.4593G>A p.Q1531= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as COSV68404008; called by muse, mutect2, varscan2
- VPS33A | c.432C>G p.L144= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV57358492; called by muse, mutect2
- XCR1 | c.561C>T p.V187= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- CDK16 | c.-394G>T | 5'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- DSTN | c.-85G>A | 5'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- EPHA10 | c.1491+664C>G | Intron (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- FSIP2 | c.-22G>C | 5'UTR (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- GDI1 | c.719+20C>T | Intron (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- MAZ | c.*194C>G | 3'UTR (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- TTC26 | c.-36C>A | 5'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- XBP1 | c.*41G>A | 3'UTR (SNP) | VAF 34/271 reads (13%) | called by muse, mutect2
- XBP1 | c.*39G>A | 3'UTR (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2
